Somatic mutation profile of tumor specimen BA2636D (aliquot aq-BA2636D) from BEATAML1.0 case 2576, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 74.4 years (27,176 days).
Specimen BA2636D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3f684390-c0fb-47a1-82e0-8f87477f71ce.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2698D (Solid Tissue Normal), aliquot aq-BA2698D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d5e98c3-3601-420a-a304-fcfe7ed4a0ec

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OR5AC2 | c.644C>G p.T215S | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT tolerated (0.23); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- MYO19 | c.288G>T p.A96= | Silent (SNP) | VAF 3/19 reads (16%) | called by muse, mutect2
